Surgical pathology report (de-identified scan), TCGA case TCGA-F7-A50G, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-F7-A50G-01A (Primary Tumor).

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

Formatted Path Reports: Tumor site: Tongue

size: 4 x 6 x 4cm

Histological grade: Well differentiated

Laterality: Midline

Tumor

Histologic type: Squamous cell carcinoma

Margins: Not specified

1CD-0-3

carcinoma, Squamous cell, nos 8070/3

Site: tongue, NOS C02.9

hw

10/29/12

Source: NCI Genomic Data Commons file aa8ed55d-4cee-430b-a01d-0f4c3c04cad8 (TCGA-F7-A50G.A7F6A2DA-136F-4D10-AAE5-4B10DD2BC984.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).